TCGA case TCGA-E7-A3X6 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c871ea6b-fbd2-4e6f-ab29-f43f6e3ddcbb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 70 years; Vital status: Dead; Days to death: 904 days (2.5 years).

Diagnoses (2)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.2; Tissue or organ of origin: Lateral wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 70.0 years (25,584 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 904 days (2.5 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 369 days (1.0 years); Days to treatment end: 407 days (1.1 years); Treatment dose: 58 Gy; Treatment outcome: Partial Response; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 620 days (1.7 years); Days to treatment end: 662 days (1.8 years); Treatment dose: 50 Gy; Treatment outcome: Partial Response; Treatment anatomic sites: Regional Site.
2. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Bone, NOS. Age at diagnosis: 71.1 years (25,953 days); Days to diagnosis: 369 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Days to follow up: 0 days; Disease response: Tumor Free.
- Day 369 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 369 days (1.0 years).
- Days to follow up: 407 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 750 days (2.1 years); Disease response: With Tumor.
- Days to follow up: 904 days (2.5 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 89 kg; Height: 170 cm; BMI: 30.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E7-A3X6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 590 mg.
  Slide TCGA-E7-A3X6-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-E7-A3X6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-E7-A3X6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: Pensioner; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Wall Lateral; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Bladder resection; Lymph nodes examined: No; Incidental prostate cancer indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 904 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 904 days; disease-free interval: event (new tumor event after initially disease-free), 369 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 369 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E7-A3X6-01A-12D-A22Y-01): tumor purity 0.71, ploidy 1.81, whole-genome doublings 0.
